Surgical pathology report (de-identified scan), TCGA case TCGA-19-1388, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1388-01A (Primary Tumor).

[page 1 of 2]
SEX: M

Pathologist:
Date Reported:
Date Received:
Submitting Physician:

FINAL DIAGNOSIS

A-C. RIGHT PARIETAL LOBE OF BRAIN, LESION, BIOPSIES:
-- MALIGNANT GLIOMA DEMONSTRATING CYTOLOGIC FEATURES CONSISTENT WITH DERIVATION
FROM GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: The tumor is densely cellular, markedly pleomorphic, and demonstrates a
brisk mitotic rate which includes atypical mitotic figures. Neither
coagulative tumor necrosis nor microvascular proliferation are identified

ENTER=CONTINUE	F1=HELP	F2=	F3=	F4=
F5=PAT SEL	F6=EXAM SUM.	F7=	F8=NEXT PAGE	F11=MORE FKEYS

[page 2 of 2]
PATIENT NAME:

BIRTHDATE:

SEX: M

PAGE 002 OF 005 FOR TEST 001 OF 001
within the biopsy specimens. Immunohistochemical stains confirm the diagnosis.

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By

Intraoperative Consult Diagnosis

ENTER=CONTINUE	F1=HELP	F2=	F3=	F4=
F5=PAT SEL	F6=EXAM SUM.	F7=PREV PAGE	F8=NEXT PAGE	F11=MORE FKEYS

Source: NCI Genomic Data Commons file b18a3b2c-a952-4ea1-af7d-25f46cbe51a5 (TCGA-19-1388.7A87E792-4AAD-479D-892D-5D515E3EB1D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).